Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3GP, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3GP-01A (Primary Tumor).

[page 1 of 2]
Diagnostic Discrepancy		☒

Surgical Pathology Report

Department of Pathology,

DOB:

Sex: M

Physician:

Accession:

Collected:

Received:

Case type: Surgical Case

1CD-0-3

carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS c73.9 11/30/11

DIAGNOSIS

- (A) RIGHT PARATRACHEAL LYMPH NODE:
METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF ONE LYMPH NODES (1/1)
Extranodal extension: Not present
- (B) TOTAL THYROID AND PORTION OF CENTRAL COMPARTMENT:
PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE
Location: Right lobe
Multi-focal: No
Size = 5.0 cm
Extrathyroidal extension: Present, extending into soft tissue and abutting skeletal muscle
Lymphovascular invasion: Present
Resection Margins: Negative
Lymph nodes: No lymph nodes present
- (C) RIGHT SUPERIOR PARATHYROID:
Parathyroid tissue present
- (D) RIGHT PARATRACHEAL DISSECTION:
METASTATIC PAPILLARY THYROID CARCINOMA IN TWO OF TWO LYMPH NODES (2/2)
Extranodal extension: Not present
- (E) RIGHT NECK DISSECTION, LEVEL III AND IV:
METASTATIC PAPILLARY THYROID CARCINOMA IN FOUR OF TWELVE LYMPH NODES (4/12)
Extranodal extension: Not present

GROSS DESCRIPTION

(A) RIGHT PARATRACHEAL LYMPH NODE – An unoriented portion of fibroadipose tissue (1.0 x 0.6 x 0.5 cm) which contains a single, 0.4 cm greatest dimension lymph node. Submitted in toto for frozen section evaluation in A.

*FS/DX: METASTATIC PAPILLARY THYROID CARCINOMA IN LYMPH NODE.

(B) TOTAL THYROID AND PORTION OF CENTRAL COMPARTMENT – Consists of a total thyroidectomy and central compartment in toto 10 x 8.5 x 3.5 cm including right lobe, 5.5 x 5.0 x 3.5 cm, isthmus 1.5 x 1.5 x 0.5 cm, and left lobe 3.5 x 2.3 x 0.8 cm.

The right lobe is nodular and distorted, and on cut section is involved almost entirely by a tan friable and partially hemorrhagic tumor, 5.0 x 5.0 x 3.0 cm in dimension. The tumor does abut the capsule, but does not appear to penetrate through it. The right lobe is also covered by skeletal muscle. The remainder of the thyroid parenchyma is unremarkable.

SECTION CODE: B1, B2, left lobe, representative; B3, isthmus, representative; B4-B10, right lobe with tumor, representative superior to inferior.

[page 2 of 2]
Surgical Pathology Report

Department of Pathology,

DOB:

Sex: M

Physician:

Collected:

Pathologist:

Accession:

Received:

Case type: Surgical Case

(C) RIGHT SUPERIOR PARATHYROID – Received is a single fragment of tan-pink soft tissue measuring 0.2 cm in greatest dimension and weighs 0.0023 grams. Touch preps are performed. The specimen is submitted entirely in C for frozen section evaluation.

*FS/DX: CONSISTENT WITH PARATHYROID.

(D) RIGHT PARATRACHEAL DISSECTION – Received is a 2.5 x 1.5 x 1.0 cm aggregate of fibroadipose tissue. The specimen is dissected to reveal two possible lymph nodes measuring 0.2 and 0.9 cm in greatest dimension. The larger possible lymph node is calcified. Specimen is submitted entirely.

SECTION CODE: D1, two possible lymph nodes; D2, remainder of the specimen is submitted entirely. D1 is submitted for decalcification.

(E) RIGHT NECK DISSECTION, LEVEL III AND IV – Received is a 4.0 x 3.0 x 2.0 cm aggregate of fibroadipose tissue. The specimen is dissected to reveal twelve possible lymph nodes ranging from 0.4 up to 1.5 cm in greatest dimension. Representative sections are submitted.

SECTION CODE: E1, four possible lymph nodes; E2, four possible lymph nodes; E3, two possible lymph nodes; E4, two possible lymph nodes.

CLINICAL HISTORY

None given.

SNOMED CODES

T-B6000, M-80503, M-B0630,

"Some tests reported here may have been developed and performance characteristics determined by
These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Page 2 of 2

Surgical Pathology Report

File under: Pathology

Source: NCI Genomic Data Commons file 8a8bdce7-e890-4d15-82be-30ab6629ee11 (TCGA-EL-A3GP.20DDD60D-D110-4CED-9956-3DA810CDFA61.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).